FM case AD11629 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Other and ill-defined sites.
https://portal.gdc.cancer.gov/cases/4e753dd5-d51a-4f5c-acdf-687c4188eea6

Male, 63.2 years: Carcinoma, NOS (ICD-O-3 8010/3) of the head, face or neck; specimen biopsied or resected from the mouth. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
